Gene-level copy-number profile of tumor specimen AP-352Q-4T from APOLLO case AP-352Q, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-352Q-4T: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aba049b7-b506-4e1e-8440-bc024dcd0790.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-352Q-XU (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/3b422bbe-a432-465a-94b7-47ec5aaaa788

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 17,018; copy number 2: 33,758; copy number 3: 7,281; copy number 4: 633; copy number 5: 3; copy number 11: 37; copy number 15: 92; copy number 19: 21; copy number 25: 15; copy number 50: 1; copy number 53: 3; copy number 57: 3; copy number 88: 7; copy number 94: 3.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,570,350–12,581,063, 2 genes: RPS3AP34, AC068587.2.
- chr21:7,744,962–8,680,934, 28 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 185 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 5: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr17:39,461,486–42,388,540, 182 genes, copy number 11–94 (within-gene range 3–94) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
